Somatic mutation profile of tumor specimen TCGA-DJ-A3V0-01A (aliquot TCGA-DJ-A3V0-01A-11D-A22Z-08) from TCGA case TCGA-DJ-A3V0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 56.1 years (20,496 days).
Specimen TCGA-DJ-A3V0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29c9a1d6-7011-467e-bb1f-53e6a09ea14b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3V0-10A (Blood Derived Normal), aliquot TCGA-DJ-A3V0-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40ddfc49-7440-497f-ad8e-01a1908db31b

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 12, Silent 7, Frame Shift Del 2, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCDC97 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs375014029; called by muse, mutect2, varscan2
- CELSR3 | c.2542A>T p.I848F | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99372798; called by muse, mutect2
- CNNM4 | c.1182del p.F394Lfs*7 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as COSV65661434; called by mutect2, pindel, varscan2
- CORO7 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV99227290; called by muse, mutect2
- CPM | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as rs764078716, COSV100614944; called by muse, mutect2, varscan2
- CTBP2 | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); catalogued as COSV100456200; called by muse, mutect2
- CTNNA3 | c.100-1G>T p.X34_splice | Splice Site (SNP) | VAF 19/50 reads (38%) | catalogued as rs1306045700, COSV100373319; called by muse, mutect2, varscan2
- EGFL8 | c.551T>C p.M184T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100246849; called by muse, mutect2
- IQCG | c.1331G>C p.*444Sext*21 | Nonstop Mutation (SNP) | VAF 14/155 reads (9%) | catalogued as COSV99502123; called by muse, mutect2
- KAT6A | c.3565A>T p.I1189F | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV99704530; called by muse, mutect2, varscan2
- NUDT17 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs782700883, COSV100566741; called by muse, mutect2, varscan2
- PPT2 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV99278253; called by muse, mutect2, varscan2
- SERPINB11 | c.354T>A p.H118Q | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.529); catalogued as COSV101236159; called by muse, mutect2, varscan2
- RGP1 | c.910_919del p.P304Sfs*14 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- USH2A | c.13817A>G p.E4606G | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDK19 | c.1419A>G p.G473= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV100098142; called by muse, mutect2, varscan2
- DMC1 | c.450C>A p.G150= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99319208; called by muse, mutect2, varscan2
- DNAH17 | c.9273C>G p.A3091= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV101101635, COSV101101831; called by muse, mutect2, varscan2
- ESR1 | c.1518G>A p.Q506= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV52781693, COSV99238163; called by muse, mutect2, varscan2
- EXD3 | c.891G>T p.P297= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100573486, COSV59804831; called by muse, mutect2, varscan2
- KMT2D | c.11029C>T p.L3677= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV99978347; called by muse, mutect2, varscan2
- PITPNM2 | c.3577C>T p.L1193= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV99759243; called by muse, mutect2
